Somatic mutation profile of tumor specimen TCGA-EB-A5VU-01A (aliquot TCGA-EB-A5VU-01A-21D-A32N-08) from TCGA case TCGA-EB-A5VU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,618 days).
Specimen TCGA-EB-A5VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c09fe46c-8660-4fa2-9e8e-063af70f9c90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5VU-10A (Blood Derived Normal), aliquot TCGA-EB-A5VU-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15046982-a4ac-435d-811b-11c64f4cbe52

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 382/479 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5578C>T p.R1860W | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs200849015, CM1311045, COSV100933022; called by muse, mutect2, varscan2
- ADAM2 | c.522A>T p.Q174H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99696706; called by muse, mutect2, varscan2
- ADCK2 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99301380; called by muse, mutect2, varscan2
- AGO2 | c.1720G>C p.V574L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as COSV99595233; called by muse, mutect2, varscan2
- CBLN2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99504129; called by muse, mutect2, varscan2
- CCDC102A | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs544503465, COSV99264786; called by muse, mutect2, varscan2
- CCDC141 | c.3568G>A p.G1190S | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99836145; called by muse, mutect2, varscan2
- CD2BP2 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99976940; called by muse, mutect2, varscan2
- CEACAM20 | c.1544C>A p.S515Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100386779; called by muse, mutect2
- DAGLA | c.2371A>T p.S791C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99943951; called by muse, mutect2, varscan2
- DISP3 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); catalogued as COSV99607325; called by muse, mutect2, varscan2
- EXOC6B | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1335077421, COSV99722815; called by muse, mutect2, varscan2
- FLRT2 | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100419981; called by muse, mutect2, varscan2
- FURIN | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs749858583, COSV51575620; called by muse, mutect2, varscan2
- HOXB5 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99494362; called by muse, mutect2, varscan2
- L3MBTL1 | c.1612A>G p.S538G (on ENST00000418998 / NM_001377303.1; = p.S448G on NM_015478.7) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100916896; called by muse, mutect2, varscan2
- LAMA5 | c.387G>C p.Q129H | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99437992; called by muse, mutect2, varscan2
- MAN2B2 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs374068742; called by muse, mutect2, varscan2
- MTG2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 33/630 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100895128; called by muse, mutect2
- MYT1 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 61/394 reads (15%) | catalogued as COSV100113913; called by muse, mutect2, varscan2
- MYT1 | c.3154C>A p.Q1052K | Missense Mutation (SNP) | VAF 166/1182 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100113923; called by muse, varscan2
- MYT1 | c.3336C>G p.I1112M | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60508784; called by muse, mutect2, varscan2
- NPTX2 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99674694; called by muse, mutect2, varscan2
- PTPRS | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs746980740, COSV53620414; called by muse, mutect2, varscan2
- REEP1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs121918262, CM063094, COSV51256355; called by muse, mutect2, varscan2
- SCP2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV101026818; called by muse, mutect2, varscan2
- TRERF1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs377409627; called by muse, mutect2, varscan2
- UBP1 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV52145657; called by muse, mutect2, varscan2
- XDH | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.464); catalogued as COSV101051971; called by muse, mutect2, varscan2
- ZAN | c.5401G>A p.A1801T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV100769135; called by muse, mutect2, varscan2
- ZNF99 | c.1807A>G p.N603D | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV101233699; called by muse, mutect2, varscan2
- ZSWIM3 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 56/738 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99666099; called by muse, mutect2
- CLCNKB | c.1323G>T p.G441= | Silent (SNP) | VAF 94/223 reads (42%) | catalogued as COSV100990187; called by muse, mutect2, varscan2
- DOK5 | c.39C>T p.Y13= | Silent (SNP) | VAF 115/173 reads (66%) | catalogued as COSV99373242; called by muse, mutect2, varscan2
- KLHL7 | c.126G>A p.T42= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs150640353; called by muse, mutect2, varscan2
- MMEL1 | c.321G>A p.P107= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs150441473; called by muse, mutect2, varscan2
- MYT1 | c.2961C>A p.V987= | Silent (SNP) | VAF 56/452 reads (12%) | catalogued as COSV100113919; called by muse, varscan2
- MYT1 | c.3090C>T p.S1030= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV100113920; called by muse, mutect2, varscan2
- MYT1 | c.3222C>T p.I1074= | Silent (SNP) | VAF 201/1490 reads (13%) | catalogued as COSV100113925; called by muse, varscan2
- OR6C65 | c.675G>A p.K225= | Silent (SNP) | VAF 41/272 reads (15%) | catalogued as COSV101110167; called by muse, mutect2, varscan2
- TFR2 | c.348G>A p.L116= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV99355419; called by muse, mutect2, varscan2
- FAM183BP | n.1063G>T | RNA (SNP) | VAF 68/177 reads (38%) | catalogued as rs547012619; called by muse, mutect2, varscan2
